FM case AD2900 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/43cadd47-7f94-4999-9702-6a16fd04ef43

Male, 64.6 years: Acinar adenocarcinoma (ICD-O-3 8550/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
